Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61J-01A (Primary Tumor).

[page 1 of 7]
PATIENT

AGE/SEX: /M

REG DR:

Received:
Copies to

Collected:

SPECIMEN ID:

- A. TONGUE - MIDDORSAL TONGUE MARGIN FS, B. TONGUE - POSTERIOR DORSAL TONGUE MARGIN FS,
- C. TONGUE - ANTERIOR DORSAL TONGUE MARGIN FS,
- D. TONGUE - POSTERIOR VENTRAL TONGUE MARGIN FS,
- E. MOUTH - POSTERIOR FLOOR OF MOUTH MARGIN FS,
- F. MOUTH - ANTERIOR FLOOR OF MOUTH MARGIN FS,
- G. TONGUE - ANTERIOR VENTRAL TONGUE MARGIN FS,
- H. TONGUE - ANTERIOR DEEP TONGUE MARGIN FS, I. TONGUE - POSTERIOR DEEP TONGUE MARGIN FS,
- J. NERVE - LINGUAL NERVE MARGIN FS, K. GLAND, NOS - LEFT SUBLINGUAL GLAND,
- L. LYMPH NODE - LEFT NECK LEVELS 2,3,4,
- M. TONGUE - LEFT GLOSSECTOMY SUTURE ANTERIOR SUPERIOR,
- N. LYMPH NODE - LEFT NECK LEVEL 1 B, O. LYMPH NODE - LEFT NECK LEVEL 1A,
- P. VEIN - LEFT EXTERNAL JUGULAR VEIN NODE, Q. VEIN - FATTY TISSUE ON LEFT FACIAL VEIN

A. MID DORSAL TONGUE MARGIN:

No malignancy seen.

B. POSTERIOR DORSAL TONGUE MARGIN:

No malignancy seen.

C. ANTERIOR DORSAL TONGUE MARGIN:

No malignancy seen.

D. POSTERIOR VENTRAL TONGUE MARGIN:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Tongue NOS C62.9
JW 5/4/13

[page 2 of 7]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

No malignancy seen.

E. POSTERIOR FLOOR OF MOUTH MARGIN:

No malignancy seen.

F. ANTERIOR FLOOR OF MOUTH MARGIN:

No malignancy seen.

G. ANTERIOR VENTRAL TONGUE MARGIN:

No malignancy seen.

H. ANTERIOR DEEP TONGUE MARGIN:

No malignancy seen.

I. POSTERIOR DEEP TONGUE MARGIN:

No malignancy seen.

J. LINGUAL NERVE MARGIN:

No malignancy seen.

K. LEFT SUBLINGUAL GLAND:

Salivary gland, no malignancy seen.

L. LEFT NECK LEVELS 2,3,4:

METASTATIC SQUAMOUS CELL CARCINOMA, 0.2 cm, to one out of sixty-three lymph nodes (1/63).

M. LEFT GLOSSECTOMY SUTURE ANTERIOR SUPERIOR:

INVASIVE WELL-DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 3.6 cm.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 3 of 7]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Surgical resection margins are free of tumor.

Perineural invasion is identified.

See Tumor Summary.

N. LEFT NECK LEVEL 1:

No malignancy seen in four lymph nodes (0/4).

Unremarkable salivary gland.

O. LEFT NECK LEVEL 1A:

METASTATIC SQUAMOUS CELL CARCINOMA, 0.5 cm, to one out of three lymph nodes (1/3).

P. LEFT EXTERNAL JUGULAR VEIN NODE:

No malignancy seen in two lymph nodes (0/2).

Q. FATTY TISSUE ON LEFT FACIAL VEIN:

No malignancy seen in one lymph node (0/1).

Surgical Pathology Cancer Case Summary

Specimen:

Lateral border of tongue

Dorsal surface of tongue

Received: In formalin

Procedure: Resection

Glossectomy (partial)

Specimen Integrity: Intact

Specimen Size: Greatest dimension: 5 x 3.5 x 1.9 cm

Specimen Laterality: Left

Tumor Site:

Lateral border of tongue

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 4 of 7]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Dorsal surface of tongue
Tumor Focality: Single focus
Tumor Size:
Greatest dimension: 2.6 cm
Additional dimensions: 1.9 x 1.6 cm
Tumor Thickness (pT1 and pT2 tumors):
Tumor thickness: 16 mm
Tumor Description:
Endophytic
Ulcerated
Histologic Type: Squamous cell carcinoma, conventional
Histologic Grade: G1: Well differentiated
Margins: Margins uninvolved by invasive carcinoma
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Present
Lymph Nodes, Extranodal Extension: Not identified
Pathologic Staging (pTNM):
Primary Tumor (pT):
pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
Regional Lymph Nodes (pN):
pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension
Number of Lymph Nodes Examined: 73
Number of Lymph Nodes Involved: 2
Size (greatest dimension) of the largest positive lymph node deposit:
0.5 cm
Distant Metastasis (pM):
Not applicable

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 5 of 7]
(Continued)

CLINICAL HISTORY-

PRE-OP DX: Not provided
PROCEDURE: Left neck dissection
RELEVANT CLINICAL HX: Not provided

GROSS DESCRIPTION:

- A. Received fresh and labeled "Mid dorsal tongue margin" is a 3.1 x 0.4 x 0.3 cm, fragment of red-tan tissue. Submitted in toto in one cassette for frozen section.
- B. Received fresh and labeled "Posterior dorsal tongue margin" is a 1.6 x 0.3 x 0.3 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- C. Received fresh and labeled "Anterior dorsal tongue margin" is a 2.7 x 0.3 x 0.3 cm, yellow-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- D. Received fresh and labeled "Posterior dorsal tongue margin" is a 1.2 x 0.3 x 0.3 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- E. Received fresh and labeled "Posterior floor of mouth" is a 1.2 x 0.3 x 0.3 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- F. Received fresh and labeled "Anterior floor of mouth margin" is a 0.9 x 0.3 x 0.3 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- G. Received fresh and labeled "Anterior ventral tongue margin" is a 1.9 x 0.3 x 0.2 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- H. Received fresh and labeled "Anterior deep tongue margin" is a 1.2 x 0.3 x 0.3 cm, yellow-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- I. Received fresh and labeled "Posterior deep tongue margin" is a 1.3 x 0.5 x 0.3 cm, red-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- J. Received fresh and labeled "Lingual nerve margin" is a 0.3 x 0.2 x 0.2 cm, white-tan soft tissue fragment. Submitted in toto in one cassette for frozen section.
- K. Received in formalin and labeled "Left sublingual gland" is a white-tan soft tissue fragment, 3.7 x 1.8 x 0.7 cm. The specimen is inked black. Submitted in toto in four cassettes.
- L. Received in formalin and labeled "Left neck levels II, III and IV" is a yellow-tan adipose tissue fragment, 8.5 x 4.5 x 3.2 cm in aggregate. Multiple lymph nodes were

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 6 of 7]
(Continued)

GROSS DESCRIPTION: (Continued)

found in the adipose tissue. The largest node measures 3.5 x 1.1 x 0.6 cm. Representative sections are submitted as follows:

Cassette #1-8: One bisected lymph node per cassette
Cassette #9: One bisected lymph node
Cassette #10-12: Four lymph nodes per cassette
Cassette #13: Six possible lymph nodes
Cassette #14-17: Nine possible lymph nodes per cassette

- M. Received in formalin and labeled "Left glossectomy" is a partial glossectomy specimen, measuring 5.0 cm from anterior to posterior, 1.9 cm from superior to inferior and 3.5 cm from medial to lateral. Serial sections reveal a 3.6 x 1.9 x 1.6 cm, white-tan lesion with surface ulceration. The lesion is located 0.3 cm from the anterior margin, 0.3 cm from the posterior margin, 0.1 cm from the deep margin, 0.5 cm from the medial margin and 0.5 cm from the lateral margin. Representative sections are submitted as follows:

Cassette #1: Tumor with deep margin
Cassette #2: Tumor with anterior margin
Cassette #3: Tumor with posterior margin
Cassette #4: Tumor with medial margin
Cassette #5: Tumor with lateral margin
Cassette #6&7: Tumor resected from the medial side
Cassette #8: Tumor resected from the lateral side

- N. Received in formalin and labeled "Left neck dissection, level IB" is a brown-tan soft tissue fragment, 4.5 x 3.4 x 2.1 cm. Four possible lymph nodes are found in the adipose tissue with presence of segment of salivary gland, 3.5 x 3.0 x 2.5 cm. The largest node measures 2.5 x 1.5 x 0.8 cm. Representative sections are submitted as follows:

Cassette #1-3: One bisected lymph node per cassette
Cassette #4: One possible lymph node with surrounding adipose tissue
Cassette #5: Section of grossly unremarkable salivary gland

- O. Received in formalin and labeled "Left neck dissection, level IA" is a yellow-tan soft tissue fragment, 5.0 x 2.5 x 1.5 cm. Three possible lymph nodes are identified. The largest node measures 1.1 x 0.7 x 0.5 cm. Representative sections are submitted as follows:

Cassette #1: Largest lymph node bisected

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 7 of 7]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #2: One lymph node bisected
Cassette #3: One lymph node bisected
Cassette #4&5: Additional adipose tissue for more lymph nodes

- P. Received in formalin and labeled "Left external jugular vein node" is a yellow-tan soft tissue fragment, measuring 2.0 x 1.7 x 0.6 cm. The specimen is bisected and submitted in toto in two cassettes.
- Q. Received in formalin and labeled "Fatty tissue on left facial vein" is a yellow-tan soft tissue, 1.5 x 0.8 x 0.5 cm. The specimen is bisected and submitted in toto in one cassette.

OPERATING ROOM CONSULT (FS-CYT)

- A. MID DORSAL TONGUE MARGIN, FS: Negative for carcinoma.
- B. POSTERIOR DORSAL TONGUE MARGIN, FS: Negative for carcinoma.
- C. ANTERIOR DORSAL TONGUE MARGIN, FS: Negative for carcinoma.
- D. POSTERIOR VENTRAL TONGUE MARGIN, FS: Negative for carcinoma.
- E. POSTERIOR FLOOR OF MOUTH MARGIN, FS: Negative for carcinoma.
- F. ANTERIOR FLOOR OF MOUTH MARGIN, FS: Negative for carcinoma.
- G. ANTERIOR VENTRAL TONGUE MARGIN, FS: Negative for carcinoma.
- H. ANTERIOR DEEP TONGUE MARGIN, FS: Negative for carcinoma.
- I. POSTERIOR DEEP TONGUE MARGIN, FS: Negative for carcinoma.
- J. LINGUAL NERVE MARGIN, FS: Negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

Source: NCI Genomic Data Commons file d9fa62da-cde8-4b63-88fd-dd7ef57e2055 (TCGA-IQ-A61J.C7D3F5D3-B898-40F0-84D1-AA0BF36A009A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).